Somatic mutation profile of tumor specimen 0DV5SJ from CCDI case PBCMCT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,609 days).
Specimen 0DV5SJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd830f15-02e6-4611-ae1d-2a47e46ee2c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/731def2e-bf0b-4f84-9b15-26f71bc3104c

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 2, Silent 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 57/145 reads (39%) | catalogued as rs747299117; called by mutect2, varscan2
- FAAH2 | c.41T>G p.L14W | Missense Mutation (SNP) | VAF 248/556 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs901557268; called by muse, mutect2, varscan2
- GAL | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1057517661, CM153944; called by muse, mutect2, varscan2
- LATS1 | c.93dup p.Q32Tfs*8 | Frame Shift Ins (INS) | VAF 142/148 reads (96%) | called by mutect2, varscan2
- ZNF782 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK1 | c.1005G>A p.P335= | Silent (SNP) | VAF 82/161 reads (51%) | catalogued as rs780334454, COSV62325724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFA9 | c.*29G>A | 3'UTR (SNP) | VAF 15/220 reads (7%) | catalogued as rs377689363; called by muse, mutect2
- PATL2 | c.223-90G>T | Intron (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
